Gene-level copy-number profile of tumor specimen ALCH-B37V-TTP1-A from ALCHEMIST case ALCH-B37V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 48.9 years (17,858 days).
Specimen ALCH-B37V-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c5fa83e6-7244-4c29-8d76-97aea1cba6c8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B37V-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/5b41eece-da51-4d23-b187-044c95574239

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 537; copy number 1: 3,679; copy number 2: 44,076; copy number 3: 10,508; copy number 4: 98; copy number 5: 13.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:5,526,409–5,563,902, 3 genes (within-gene range 0–2): ACTB, AC006483.2, AC006483.1.
- chr9:65,189,995–65,193,610, 1 gene: BMS1P12.
- chr12:57,819,927–57,846,729, 3 genes (within-gene range 0–2): CTDSP2, MIR26A2, AC083805.2.
- chr17:8,224,815–8,297,216, 6 genes: CTC1, PFAS, AC135178.6, SLC25A35, RANGRF, AC135178.7.
- chr18:37,273,706–37,306,333, 2 genes (within-gene range 0–2): AC090386.1, AC090386.2.
- chr19:3,172,346–3,180,332, 1 gene: S1PR4.
- chr19:44,890,569–44,949,565, 8 genes (within-gene range 0–2): TOMM40, APOE, AC011481.3, APOC1, APOC1P1, APOC4, APOC4-APOC2, APOC2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:131,423,921–131,635,231, 1 gene, copy number 5 (within-gene range 3–5): RAPGEF6.
- chr5:131,440,031–131,440,196, 1 gene, copy number 5 (within-gene range 3–5): AC008497.1.
- chr15:101,903,154–101,979,093, 10 genes, copy number 5: AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.

Autosomal genes at a single copy (total copy number 1): 2,099. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
